Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4174, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4174-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

Patient with incidental right renal mass, 9.4 x 7.8 cm.

Specimens Submitted:

- 1: SP: Right kidney
- 2: SP: Paracaval nodes
- 3: SP: Right adrenal

DIAGNOSIS:

- 1) KIDNEY, RIGHT; NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL CLEAR CELL TYPE, NUCLEAR GRADE III/IV.
- THE TUMOR GREATEST DIAMETER IS 9.4 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- UNINVOLVED KIDNEY SHOWS CHRONIC INFLAMMATION.
- 2) LYMPH NODE, PARACAVAL; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 3) ADRENAL GLAND, RIGHT; ADRENALECTOMY:
- BENIGN ADRENAL GLAND.
- NO TUMOR SEEN.

Gross Description:

1) The specimen is received fresh, labeled "Right kidney". It consists of a right radical nephrectomy with attached adipose tissue weighing 704 gm and measuring 15.2 x 10.4 x 4.5 cm. Most of the adipose tissue is on one of the poles of the kidney and measures 10.5 x 15.2 x 1.0 cm. The opposite pole is distorted by a mass. Sections through the kidney reveal a well-circumscribed tumor measuring 9.4 x 8.4 cm. The center of the tumor has a yellow scar. The surrounding area has a variegated look ranging from yellow to red to tan. The tumor is very fragile and focally cystic. The tumor approximates the pelvis but does not seem to be extending into the ureter, the renal vein, or the artery. The tumor is very hemorrhagic and is limited by the renal capsule and does not extend into the overlying adipose tissue. No adrenal gland is identified. Portions of the specimen has been photographed and a portion has been submitted for TPS. Representative section is submitted.

Summary of Sections:

HM - hilar margin
RSFT - renal sinus fat with tumor

[page 2 of 2]
[REDACTED]

[REDACTED]

RPT - renal parenchymal tumor
AKT - adjacent kidney with tumor
T - tumor
NKI - normal kidney
UM -- ureteral margin

[REDACTED]

2) The specimen is received in formalin, labeled "Paracaval nodes". It consists of two irregular pieces of adipose tissue measuring 3.5 x 2.9 x 0.9 cm and 3.6 x 1.5 x 0.4 cm. All the identified lymph nodes are submitted along with the remaining adipose tissue.

Summary of Sections:
LN - lymph nodes
ADP - adipose tissue

[REDACTED]

3) The specimen is received in formalin, labeled "Right adrenal". It consists of a focally disrupted adrenal gland with overlying adipose tissue measuring 7.1 x 2.5 x 1.0 cm. The cut section shows hemorrhagic and otherwise appears unremarkable. Representative sections submitted.

Summary of Sections:
U - undesiguated

Summary of Sections:

Part 1: SP: Right kidney [REDACTED]

Block	Sect. Site	PCs
1	akt	1
1	hm	1
1	nki	1
2	rpt	2
3	rsft	3
6	t	6
1	um	1

Part 2: SP: Paracaval nodes (sr)

Block	Sect. Site	PCs
4	adp	4
1	ln	1

Part 3: SP: Right adrenal (sr)

Block	Sect. Site	PCs
3	u	3

Source: NCI Genomic Data Commons file afd2326c-b613-478a-8e5e-56280aa9fff4 (TCGA-BP-4174.6FD40018-B7B1-4EA2-B31B-BBD4BE3EFF22.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).